Surgical pathology report (de-identified scan), TCGA case TCGA-RY-A840, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of California San Francisco, specimen TCGA-RY-A840-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Soc. Sec. #: [REDACTED]

Physician(s): [REDACTED]

Visit #: [REDACTED]

Sex: Male

Location: [REDACTED]

Accession #: [REDACTED]

Service Date: [REDACTED]

Received: [REDACTED]

Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

A. Brain, left temporal lobe, biopsy: Anaplastic oligodendroglioma, WHO grade III; see comment.

B. Brain, left temporal lobe, biopsy: Anaplastic oligodendroglioma, WHO grade III; see comment.

C. Brain, left temporal lobe, resection: Anaplastic oligodendroglioma, WHO grade III; see comment.

COMMENT:

Sections demonstrate an extensively infiltrating oligodendroglioma involving adjacent cortex (best demonstrated on section B1). Mitotic figures are identified (5 MF/10 HPF). Scattered foci of microvascular proliferation are present, supporting the diagnosis of anaplastic oligodendroglioma. Immunohistochemistry for MIB-1 will be performed and evaluated on blocks A2 and B1, and the findings will be reported in an addendum. In addition, level sections on block B1 as well as immunohistochemistry for p53 and IDH-1 (R132H mutant form) on block A2 will be performed, and the results will be reported in an addendum to follow.

Fluorescence in situ hybridization (FISH) for 1p19q will be performed at the on block A2, and the findings will be reported in a separate report.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

ICD-O-3
Oligodendroglioma, grade III 9451/3
Date CSCE
path Brain, supratentorial NOS C71.0
Brain, temporal lobe C71.2
(1) 10/30/12

[page 2 of 2]
Intraoperative Diagnosis

FS1 (A) Brain, left temporal lobe, biopsy: Anaplastic oligodendroglioma, WHO grade III. Tissue section and cytologic preparation.

Gross Description

The specimen is received fresh in three parts, each labeled with the patient's name and medical record number.

Part A, additionally labeled "tumor," consists of multiple soft irregular pieces of off-white/red tissue (1.1 x 1 x 0.2 cm in aggregate). A portion of the specimen is submitted frozen for frozen section diagnosis 1 and cytologic preparation, and the frozen section remnant is entirely submitted in cassette A1. The remaining unfrozen tissue is entirely submitted in cassette A2.

Part B, additionally labeled "permanent = brain tumor," consists of two unoriented, ovoid fragments of pink to deep-red, glistening soft tissue (0.8 x 0.6 x 0.2 cm and 0.9 x 0.7 x 0.3 cm). The specimen is entirely submitted in cassette B1.

Part C, additionally labeled "CUSA trap - permanent," consists of multiple irregular, friable pale tan to pink-red, glistening soft tissue fragments (4 x 2.5 x 0.8 cm in aggregate). The specimen is entirely submitted in cassettes C1-C6.

Clinical History

The patient is a -year-old male who presented with seizures and was found on MRI brain scan to have a left temporal lobe lesion with central enhancement and increased cerebral blood volume, most compatible with a malignant glioma. The patient undergoes resection.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

/Pathology Resident

/Pathologist

Signed:

Addendum

Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out
By:

Addendum Comment

The tumor cells are strongly positive for IDH1 (R132H mutant form) and negative for P53. The proliferative index assessed by MIB1 is estimated at 5%.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the . They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

/Pathologist
Resident

IHPAA Discrepancy		✓

Source: NCI Genomic Data Commons file ce84a40a-5972-4a72-a941-6286ad84e481 (TCGA-RY-A840.D0ABD0C6-7F14-4CC3-9B44-0566D3384727.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).